Gene-level copy-number profile of tumor specimen C3L-05518-01 from CPTAC case C3L-05518, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 80.0 years (29,238 days).
Specimen C3L-05518-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e17a0a2d-68db-46fb-9100-299dd5454c3b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-05518-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/6abe8be0-0315-42e2-83f4-9fbe24215cc2

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 39; copy number 1: 622; copy number 2: 15,909; copy number 3: 20,006; copy number 4: 17,249; copy number 5: 2,566; copy number 6: 133; copy number 7: 178; copy number 8: 1,636; copy number 9: 36; copy number 12: 20.

Homozygous deletions (total copy number 0; autosomes only): 39 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:3,700,492–3,700,628, 1 gene (within-gene range 0–3): RNA5SP251.
- chr8:5,659,679–6,708,224, 14 genes: AC084768.1, AC084768.2, AC087369.1, RN7SKP159, AC079054.1, AC009435.1, AC016065.1, MCPH1, AC016065.2, ANGPT2, AC018398.2, AF287957.1, MCPH1-AS1, MIR8055.
- chr8:9,453,698–9,782,346, 5 genes (within-gene range 0–3): AC021242.1, AC021242.3, TNKS, AC103834.1, MIR597.
- chr8:11,676,959–11,763,223, 2 genes: GATA4, C8orf49.
- chr8:12,333,644–12,400,366, 7 genes: RNA5SP254, DEFB108E, ZNF705CP, FAM66A, AC087203.1, AC087203.2, DEFB109A.
- chr8:13,160,178–13,160,279, 1 gene (within-gene range 0–3): Y_RNA.
- chr8:14,487,776–14,487,879, 1 gene (within-gene range 0–3): RNU6-397P.
- chr8:22,877,972–22,897,813, 2 genes (within-gene range 0–3): AC037441.1, AC037441.2.
- chr9:12,098,660–12,300,451, 3 genes: AL589678.1, JKAMPP1, RNU2-47P.
- chr9:21,966,929–21,967,751, 1 gene (within-gene range 0–2): CDKN2A-DT.
- chr10:79,825,902–79,850,878, 2 genes (within-gene range 0–2): AL135925.1, NUTM2E.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,870 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:83,522,814–86,364,265, 72 genes, copy number 7–12 (broad region; genes not listed).
- chr2:86,505,668–86,721,122, 1 gene, copy number 7 (within-gene range 5–7): RNF103-CHMP3.
- chr2:86,562,070–92,035,000, 166 genes, copy number 7–9 (within-gene range 5–9) (broad region; genes not listed).
- chr3:66,998,307–74,136,892, 85 genes, copy number 7–8 (broad region; genes not listed).
- chr3:77,811,741–79,767,998, 11 genes, copy number 7 (within-gene range 6–7): RNU6-217P, LINC02077, AC117462.1, RN7SL647P, RN7SKP61, AC108752.1, MRPS17P3, ROBO1, AC055731.1, RN7SL751P, AC117461.1.
- chr3:88,317,156–88,950,928, 5 genes, copy number 7: ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2.
- chr3:197,298,252–198,043,720, 25 genes, copy number 7 (within-gene range 5–7): DLG1-AS1, AC128709.2, AC128709.1, AC128709.3, LINC02012, BDH1, AC132008.2, AC132008.1, AC024560.2, AC024560.3, AC024560.1, AC024560.5, RUBCN, MIR922, FYTTD1, AC055764.2, LRCH3, AC055764.1, AC144530.1, IQCG, RNU6-858P, RPL35A, LMLN, RNU6-621P, AC135893.1.
- chr8:18,370,607–18,401,218, 5 genes, copy number 7: NATP, AC025062.1, AC025062.3, AC025062.2, NAT2.
- chr8:38,901,235–39,105,445, 6 genes, copy number 7: PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D.
- chr8:46,028,804–145,066,685, 1,494 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 622. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
